FM case AD9939 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/24a71a42-aa7d-4329-8c95-62fe4a2e982b

Female, 66.2 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
